Somatic mutation profile of tumor specimen TCGA-2Y-A9H8-01A (aliquot TCGA-2Y-A9H8-01A-11D-A38X-10) from TCGA case TCGA-2Y-A9H8, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 85.8 years (31,322 days).
Specimen TCGA-2Y-A9H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dcd3aac-dbc7-48ce-9842-e5629521b116.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9H8-10A (Blood Derived Normal), aliquot TCGA-2Y-A9H8-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a93e45e-4802-42cd-9041-67e6ec68c6ea

The open-access MAF lists 86 somatic variants for this specimen: 60 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 23, Splice Site 3, Intron 3, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 57/98 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2621T>C p.V874A | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as rs565619660, COSV99713168; called by muse, mutect2
- ABI3BP | c.1955G>C p.R652T | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99426987; called by muse, mutect2, varscan2
- ACE | c.2822G>A p.W941* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99327117; called by muse, mutect2, varscan2
- ACRBP | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs756765669, COSV99975951; called by muse, mutect2, varscan2
- ADHFE1 | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs756778589, COSV52557853, COSV99397887; called by muse, mutect2, varscan2
- APBA3 | c.518A>C p.E173A | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100349674; called by muse, mutect2, varscan2
- APCS | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99661339; called by muse, mutect2, varscan2
- ARHGEF10 | c.1045C>T p.L349F (on ENST00000398564; = p.L324F on NM_014629.4) | Missense Mutation (SNP) | VAF 126/246 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100034605; called by muse, mutect2
- ATP13A4 | c.3465G>T p.Q1155H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100710304; called by muse, mutect2, varscan2
- CFAP45 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs753278916, COSV100928591; called by muse, mutect2, varscan2
- CFAP61 | c.1340C>A p.T447N | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.503); catalogued as COSV55646698, COSV99845096; called by muse, mutect2, varscan2
- CPEB3 | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs761798097, COSV99799595; called by muse, mutect2, varscan2
- CRTC1 | c.722A>T p.N241I | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV100119369; called by muse, mutect2, varscan2
- DUSP8 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs762127578, COSV100524195; called by muse, mutect2, varscan2
- EPB41L4B | c.1394A>G p.H465R | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.622); catalogued as COSV101000542; called by muse, mutect2, varscan2
- EPHB3 | c.1645G>T p.G549W | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.535); catalogued as COSV100383099; called by muse, mutect2, varscan2
- ERN1 | c.1236A>C p.E412D | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101458452; called by muse, mutect2, varscan2
- FLNC | c.5996G>A p.R1999Q | Missense Mutation (SNP) | VAF 114/151 reads (75%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as rs1346364708, COSV57953622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMN2 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as COSV60452833; called by muse, mutect2, varscan2
- GGA2 | c.1450+1G>C p.X484_splice | Splice Site (SNP) | VAF 190/291 reads (65%) | catalogued as COSV100564713; called by muse, mutect2, varscan2
- GLI3 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs375277249, COSV67887297; called by muse, mutect2, varscan2
- GPR101 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs766985500, COSV99981445; called by muse, mutect2, varscan2
- HDAC5 | c.2890G>C p.D964H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99291257; called by muse, mutect2, varscan2
- HOXA2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 35/684 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99761238; called by muse, mutect2
- LGALS9B | c.529C>A p.R177S | Missense Mutation (SNP) | VAF 156/241 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as rs999199761, COSV100162965; called by muse, mutect2, varscan2
- LMOD1 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368400320; called by muse, mutect2, varscan2
- LRFN5 | c.277C>A p.H93N | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.348); catalogued as COSV99984077; called by muse, mutect2, varscan2
- MCTP2 | c.1269G>T p.K423N | Missense Mutation (SNP) | VAF 83/135 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100537497; called by muse, mutect2, varscan2
- MIA3 | c.14C>G p.P5R | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100738401; called by muse, mutect2, varscan2
- MSH4 | c.1907-2A>C p.X636_splice | Splice Site (SNP) | VAF 28/124 reads (23%) | catalogued as COSV54206228; called by muse, mutect2, varscan2
- MYO10 | c.2027G>T p.R676L | Missense Mutation (SNP) | VAF 55/414 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99945499; called by muse, mutect2, varscan2
- NCSTN | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99667193; called by muse, mutect2, varscan2
- NKAP | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 100/144 reads (69%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV101004234; called by muse, mutect2, varscan2
- NOX3 | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 75/117 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV99343213; called by muse, mutect2, varscan2
- OR4K17 | c.668T>A p.I223K | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs1432320250, COSV100210680; called by muse, mutect2
- PATJ | c.4567T>G p.Y1523D | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs749661534, COSV100334370; called by muse, mutect2, varscan2
- POM121L12 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV68693557; called by muse, mutect2
- PPP5C | c.1435G>C p.V479L | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99183229; called by muse, mutect2, varscan2
- PRKCZ | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs777236443, COSV66071277; called by muse, mutect2, varscan2
- PTBP1 | c.944C>T p.S315L (on ENST00000349038 / NM_031991.4; = p.S341L on NM_002819.5) | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs375905582, COSV100608745; called by muse, mutect2, varscan2
- RBMS3 | c.190T>A p.Y64N | Missense Mutation (SNP) | VAF 132/311 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99821838; called by muse, mutect2, varscan2
- RETNLB | c.303C>A p.D101E | Missense Mutation (SNP) | VAF 164/260 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV99848807; called by muse, varscan2
- RUFY4 | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 113/241 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100723081; called by muse, mutect2, varscan2
- SF3B3 | c.2940A>T p.K980N | Missense Mutation (SNP) | VAF 75/113 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100209952; called by muse, mutect2, varscan2
- SLC12A5 | c.36dup p.A13Rfs*8 | Frame Shift Ins (INS) | VAF 6/51 reads (12%) | catalogued as rs1254381660; called by pindel, varscan2
- SWAP70 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 135/290 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs756992212, COSV59666869; called by muse, mutect2, varscan2
- SYT10 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99951456; called by muse, mutect2, varscan2
- TACC2 | c.3983G>T p.C1328F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100552460; called by muse, mutect2, varscan2
- TAF9B | c.152T>G p.L51R | Missense Mutation (SNP) | VAF 178/275 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100540687; called by muse, mutect2, varscan2
- TMEM39B | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs202154275; called by muse, mutect2, varscan2
- TTC30A | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs763287704, COSV100826194, COSV63100918; called by muse, mutect2, varscan2
- VCX | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 52/348 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.441); catalogued as rs768350961, COSV58233177; called by muse, mutect2, varscan2
- VCX2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.368); catalogued as rs771797452; called by mutect2, varscan2
- ZDHHC17 | c.288G>T p.W96C | Missense Mutation (SNP) | VAF 238/492 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58351222; called by muse, varscan2
- ZGRF1 | c.2726C>T p.S909F | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100005563; called by muse, mutect2, varscan2
- AKAP6 | c.31dup p.L11Pfs*12 | Frame Shift Ins (INS) | VAF 13/152 reads (9%) | called by mutect2, pindel
- H6PD | c.1167_1189del p.Q390Afs*99 | Frame Shift Del (DEL) | VAF 58/161 reads (36%) | called by mutect2, pindel, varscan2
- MCCC1 | c.1367_1377+10del p.X456_splice | Splice Site (DEL) | VAF 57/179 reads (32%) | called by mutect2, pindel, varscan2
- RASL11A | c.459del p.H153Qfs*13 | Frame Shift Del (DEL) | VAF 103/185 reads (56%) | called by mutect2, pindel, varscan2
- AEBP1 | c.2994G>A p.G998= | Silent (SNP) | VAF 56/141 reads (40%) | catalogued as COSV99788815; called by muse, mutect2, varscan2
- BDP1 | c.1086T>C p.F362= | Silent (SNP) | VAF 75/307 reads (24%) | catalogued as COSV100703159; called by muse, mutect2, varscan2
- CANT1 | c.477G>A p.A159= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as rs149367726; called by muse, mutect2, varscan2
- DNAH1 | c.8532G>A p.E2844= | Silent (SNP) | VAF 50/94 reads (53%) | catalogued as COSV101325965; called by muse, mutect2, varscan2
- IER3 | c.153C>T p.R51= | Silent (SNP) | VAF 49/206 reads (24%) | catalogued as COSV99458210; called by muse, mutect2, varscan2
- IGKV6-21 | c.81A>G p.P27= | Silent (SNP) | VAF 69/217 reads (32%) | called by muse, mutect2, varscan2
- ITGA4 | c.1230C>T p.I410= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV52005400, COSV99276393; called by muse, mutect2, varscan2
- KLHL11 | c.18G>A p.V6= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100044347; called by muse, mutect2, varscan2
- KRT38 | c.120T>C p.I40= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as COSV99878239; called by muse, mutect2, varscan2
- MEX3C | c.1188A>T p.G396= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs140545981; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1428G>A p.P476= | Silent (SNP) | VAF 116/176 reads (66%) | catalogued as rs781525826, COSV100186734; called by muse, varscan2
- MROH5 | c.3438G>A p.G1146= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100267242; called by muse, mutect2, varscan2
- MUC16 | c.13155G>T p.V4385= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as COSV101200046; called by muse, mutect2
- PDE8A | c.1098C>T p.A366= | Silent (SNP) | VAF 228/323 reads (71%) | catalogued as COSV100051947; called by muse, mutect2, varscan2
- POLE | c.588G>A p.Q196= | Silent (SNP) | VAF 73/103 reads (71%) | catalogued as COSV100266906; called by muse, mutect2, varscan2
- SLC8A2 | c.1074G>A p.T358= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV52643414; called by muse, mutect2, varscan2
- SMC3 | c.1353G>A p.L451= | Silent (SNP) | VAF 160/670 reads (24%) | catalogued as COSV100699930; called by muse, mutect2, varscan2
- SPEG | c.5904C>A p.A1968= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV100404626; called by muse, mutect2, varscan2
- TMEM132E | c.633G>A p.R211= (on ENST00000321639; = p.R301= on NM_001304438.2) | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100396376; called by muse, mutect2, varscan2
- ULK4 | c.3150C>T p.T1050= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV100092731, COSV100092976; called by muse, mutect2, varscan2
- USP42 | c.48T>C p.Y16= | Silent (SNP) | VAF 63/165 reads (38%) | catalogued as COSV100084515; called by muse, mutect2, varscan2
- WDR90 | c.2061G>A p.T687= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs577796944, COSV99553491; called by muse, mutect2, varscan2
- ZDHHC15 | c.642T>A p.L214= | Silent (SNP) | VAF 415/635 reads (65%) | catalogued as COSV100973786; called by muse, mutect2, varscan2
- DAPK3 | c.630-277G>A | Intron (SNP) | VAF 20/111 reads (18%) | catalogued as COSV100009699; called by muse, mutect2, varscan2
- HELT | c.27+31G>A | Intron (SNP) | VAF 78/120 reads (65%) | catalogued as COSV100132911; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86034C>T | Intron (SNP) | VAF 19/64 reads (30%) | catalogued as rs747384089, COSV72277400, COSV72278078; called by muse, mutect2, varscan2
